FM case AD8467 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/3ebf368e-2539-46b5-830b-8224a0316e68

Female, 26.5 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the peritoneum; primary biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
